Somatic mutation profile of tumor specimen 0DIW7T from CCDI case PBBWAV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 5.1 years (1,864 days).
Specimen 0DIW7T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5df0103-fc4f-4d08-b8d6-676a34dc765f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW65 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d521fe2-8f9e-4a62-bd3d-fae53d70415a

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCAM2 | c.2409G>T p.L803F | Missense Mutation (SNP) | VAF 100/546 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV99525671; called by muse, mutect2, varscan2
- AKAP9 | c.5381A>G p.K1794R (on ENST00000359028; = p.K1762R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 386/635 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- HDAC6 | c.311+59A>G | Intron (SNP) | VAF 68/110 reads (62%) | called by muse, varscan2
